Surgical pathology report (de-identified scan), TCGA case TCGA-IB-7890, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Alberta Health Services, specimen TCGA-IB-7890-01A (Primary Tumor).

[page 1 of 3]
ORIGINAL REPORT

SPECIMEN:

- A: Distal pancreas and spleen
- B: Gallbladder

CLINICAL HISTORY:

Pancreatic cancer.

DIAGNOSIS:

A: PANCREAS, DISTAL:

- INVASIVE POORLY DIFFERENTIATED DUCTAL ADENOCARCINOMA (2.8 CM).
- RESECTION MARGINS NEGATIVE FOR MALIGNANCY.
- LYMPHVASCULAR (VENOUS) INVASION BY TUMOR.
- 11/11 LYMPH NODES, NEGATIVE FOR MALIGNANCY.
- POSITIVE FOR PERINEURAL INVASION.

SPLEEN:

- WITHIN NORMAL LIMITS.

OMENTUM:

- ACCESSORY SPLENULE IDENTIFIED.

B: GALLBLADDER, CHOLECYSTECTOMY:

- CHOLELITHIASIS.
- INTESTINAL METAPLASIA WITHOUT DYSPLASIA.

GROSS DESCRIPTION:

A: The specimen consists of pancreatic tail (5.0 cm in length x 4.5 x 2.2 cm), spleen (9.9 x 8.8 x 5.5 cm), and attached portion of fatty tissue (19.5 x 10.5 x 3.8 cm). The entire specimen is painted with silver nitrate. The proximal pancreatic resection margin is painted blue.

On cut section of the pancreas, there is white, firm, fibrotic tumor measuring 2.8 x 2.5 x 1.5 cm in width. The tumor is located 1.3 cm from the surgical

[page 2 of 3]
HISTOPATHOLOGY REPORT

Division Head:

Inquiry Numbers

GROSS DESCRIPTION:

pancreatic resection margin, 1.1 cm from the superior resection margin, 1.1 cm from the inferior soft tissue resection margin, and 0.6 cm from the the posterior soft tissue resection margin. The tumor is abutting but not involving the splenic vein. The tumor does not extend into the splenic hilum soft tissue. The splenic tissue is unremarkable. Upon the attached omental fat, there is a 0.6 cm attached splenule. The remaining fatty tissue is grossly unremarkable.

The specimen is submitted as follows:

- A1 and A2 - painted blue resection margin.
- A3 - vascular margins,
- A4 - tumor and closest superior margin.
- A5 - tumor and closest posterior margin.
- A6 - tumor and closest inferior margin.
- A7 through A9 - representative sections of tumor.
- A10 - representative section of spleen.
- A11 - splenule bisected.
- A12 - thrombosed vessel in splenic hilum.
- A13 - normal appearing pancreas.
- A14 - potential lymph node (hilar spleen).
- A15 - four putative lymph nodes.
- A16-19, additional lymph nodes

B: The specimen consists of a cholecystectomy specimen (9.1 cm in length and up to 4.5 cm in diameter). The entire specimen is painted with silver nitrate. The outer surface of the gallbladder is smooth and unremarkable. The lumen contains enumerable numbers of yellow cholesterol stones with hemorrhagic centers ranging in size between 1.0 cm and 0.1 cm. The gallbladder wall is thin (measuring 0.1 cm in greatest thickness), and attenuated.

Representative sections of the gallbladder wall and resection margin are submitted in cassette B.

MICROSCOPIC DESCRIPTION:

Sections of pancreas demonstrate a pancreatic intraductal neoplasia of low grade dysplasia (panIN 1) that extends to resection margin.

[page 3 of 3]
HISTOPATHOLOGY REPORT

Division Head:

Inquiry Numbers:

RESIDENT:

Source: NCI Genomic Data Commons file 654ec13a-9a7f-4ff9-872d-c24ddc74237a (TCGA-IB-7890.52E72F20-35E1-40DB-B9E0-7DED4A7479E6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).